Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29A, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29A-06A (Metastatic).

DCB/Age/Sex
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

1CD-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous tissue,
- abdominal wall
C49.4

6/2/11

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Melanoma L posterior back. 2.5mm Clark 4. MIT = 6/mm² 2003. Multiple intransit recurrences. EO nodules anterior abdominal wall (subcutaneous). 1. Right. 2. Left.

MACROSCOPIC DESCRIPTION

Two specimens were received.

1. "LEFT ANTERIOR ABDOMINAL WALL". Fibroadipose tissue 40 x 25 x 20mm containing a nodule 13mm in diameter. Portion of the nodule taken for tumour banking.

- A. One transverse section.
- B. Tumour with closest margin
- Representative sections.

2. "RIGHT ANTERIOR ABDOMINAL WALL". Fibroadipose tissue 35 x 25 x 25mm containing a nodule 15mm in diameter. A portion of the nodule taken for tumour banking. The tumour lies 1mm from the closest margin. One transverse section embedded.

MICROSCOPIC REPORT

1. "LEFT ANTERIOR ABDOMINAL WALL". The sections show fibrofatty tissue with a large deposit of large malignant cells. The appearances of the tumour are similar to the melanoma excised previously. Some tumour can be seen infiltrating a small peripheral nerve twig. The tumour is narrowly excised with a clearance of about 0.4mm from the nearest surgical excision margin.

2. "RIGHT ANTERIOR ABDOMINAL WALL". The sections show fibrofatty tissue with a large nodule of metastatic malignant cells consistent with metastatic melanoma. There is also a small satellite deposit of tumour approximately 0.9mm in diameter present and this extends close to the surgical excision margin with a clearance of about 0.35mm.

SUMMARY

1. Subcutaneous tissue from left abdominal wall - Metastatic malignant melanoma.
2. Subcutaneous tissue from right anterior abdominal wall - Metastatic malignant melanoma.

REPORTED BY Prof

6/2/11

Printed:

Page 1 of 1

Source: NCI Genomic Data Commons file 56f808be-4102-47ef-8331-dea6e6469006 (TCGA-EE-A29A.C2052509-2335-4B8B-8581-4D2B79D36B25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).